Somatic mutation profile of tumor specimen C3N-03019-02 (aliquot CPT0189030006) from CPTAC case C3N-03019, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.3 years (16,917 days).
Specimen C3N-03019-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c78e03dd-ea08-4ac8-bcf7-e18938f29f9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03019-31 (Blood Derived Normal), aliquot CPT0189070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147d081d-bbe7-4a56-ac1b-d2558cc59aee

The open-access MAF lists 48 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Intron 5, Frame Shift Del 4, Splice Site 3, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELOC | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 34/135 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV53022646, COSV53022661, COSV53024355; called by muse, mutect2, varscan2
- AMER3 | c.1904C>A p.P635H | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV58465202; called by muse, mutect2, varscan2
- AQP6 | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145050895; called by muse, mutect2
- CACNA1S | c.4573G>A p.A1525T | Missense Mutation (SNP) | VAF 139/570 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760097708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 103/381 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.719); catalogued as rs368809767; called by muse, mutect2, varscan2
- FRAS1 | c.860A>C p.Y287S | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as rs193116988, COSV53596363, COSV53635196; called by muse, mutect2, varscan2
- KIAA1549L | c.2257A>T p.T753S (on ENST00000321505; = p.T1050S on NM_012194.3) | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99684471; called by muse, mutect2
- AFF1 | c.1317+2T>G p.X439_splice | Splice Site (SNP) | VAF 69/283 reads (24%) | called by muse, mutect2, varscan2
- AKAP6 | c.251T>A p.V84D | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP4 | c.403A>C p.I135L | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC168 | c.17876_17885del p.S5959Ifs*7 | Frame Shift Del (DEL) | VAF 62/284 reads (22%) | called by mutect2, pindel*, varscan2*
- DEF8 | c.1336G>C p.A446P | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- FZD5 | c.1277T>A p.L426H | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR1 | c.3705G>T p.M1235I (on ENST00000354582; = p.M1220I on NM_002222.7) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KIAA1549L | c.3305A>T p.K1102I (on ENST00000321505; = p.K1399I on NM_012194.3) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- MOCS3 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 125/488 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- NRP1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PATJ | c.3293del p.E1098Gfs*11 | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | called by mutect2, pindel, varscan2
- PEAK3 | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- SIPA1L3 | c.728_731del p.R243Qfs*62 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- SLC35B3 | c.345del p.T116Pfs*2 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | called by mutect2, pindel, varscan2
- SLC41A1 | c.481-1G>A p.X161_splice | Splice Site (SNP) | VAF 99/398 reads (25%) | called by muse, mutect2, varscan2
- TARDBP | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TIAM1 | c.1739T>A p.M580K | Missense Mutation (SNP) | VAF 86/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TMEM185A | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.60604A>G p.S20202G (on ENST00000591111; = p.S12778G on NM_003319.4) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP34 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZFHX4 | c.7814A>G p.D2605G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF189 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBA3 | c.1452C>A p.T484= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV53662619; called by muse, mutect2, varscan2
- DSP | c.1164T>C p.T388= | Silent (SNP) | VAF 21/590 reads (4%) | called by muse, mutect2
- HECW1 | c.1629G>A p.E543= | Silent (SNP) | VAF 73/312 reads (23%) | called by muse, mutect2, varscan2
- MOV10 | c.372G>T p.V124= | Silent (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- PAK5 | c.720A>G p.A240= | Silent (SNP) | VAF 17/405 reads (4%) | called by muse, mutect2
- PLPPR3 | c.648C>T p.V216= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- PML | c.2160G>T p.G720= | Silent (SNP) | VAF 25/572 reads (4%) | called by muse, mutect2
- PPP4R4 | c.909C>T p.F303= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV58556864; called by mutect2, varscan2
- RGS2 | c.57C>T p.S19= | Silent (SNP) | VAF 22/578 reads (4%) | catalogued as COSV99343239; called by muse, mutect2
- TAS1R3 | c.1143G>A p.V381= | Silent (SNP) | VAF 17/433 reads (4%) | catalogued as COSV59563924; called by muse, mutect2
- ZBTB45 | c.894C>A p.V298= | Silent (SNP) | VAF 41/163 reads (25%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3456C>A | Intron (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- CA5BP1 | n.452G>T | RNA (SNP) | VAF 18/158 reads (11%) | catalogued as rs917635640; called by muse, mutect2, varscan2
- CA5BP1 | n.453C>T | RNA (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- CCSAP | c.368-538C>G | Intron (SNP) | VAF 45/217 reads (21%) | called by muse, mutect2, varscan2
- COG3 | c.2458-18C>A | Intron (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- FAM161A | c.184-4608T>C | Intron (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- GNAT1 | c.-20C>T | 5'UTR (SNP) | VAF 52/216 reads (24%) | called by muse, mutect2, varscan2
- KCNH2 | c.2398+86G>T | Intron (SNP) | VAF 125/566 reads (22%) | called by muse, mutect2, varscan2
